Somatic mutation profile of tumor specimen TCGA-85-8276-01A (aliquot TCGA-85-8276-01A-11D-2293-08) from TCGA case TCGA-85-8276, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.2 years (22,707 days).
Specimen TCGA-85-8276-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fb8aca0-8ff4-4a19-97a6-307118f8dc39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8276-10A (Blood Derived Normal), aliquot TCGA-85-8276-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ca1ba79-dcbd-4696-b735-b3498cfece8a

The open-access MAF lists 287 somatic variants for this specimen: 208 protein-altering or splice-affecting, 73 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 185, Silent 73, Nonsense Mutation 12, Splice Site 4, Frame Shift Ins 3, Frame Shift Del 2, RNA 2, Nonstop Mutation 2, 3'UTR 2, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA3 | c.4474G>A p.G1492R | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as rs781268210, COSV100067988, COSV100067991; called by muse, mutect2, varscan2
- ABCC2 | c.2675A>T p.E892V | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as COSV100966387; called by muse, mutect2, varscan2
- ACTN4 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99399757; called by muse, mutect2
- ADGRG2 | c.2394T>A p.F798L (on ENST00000379869 / NM_001079858.3; = p.F795L on NM_005756.4) | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as COSV100491872; called by muse, mutect2, varscan2
- ANO4 | c.2267G>T p.W756L (on ENST00000392977 / NM_001286615.2; = p.W721L on NM_178826.4) | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.717); catalogued as COSV100151941, COSV54592247; called by muse, mutect2, varscan2
- APCDD1L | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs923267133, COSV100953923; called by muse, mutect2, varscan2
- ARHGAP33 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV99137562; called by muse, mutect2, varscan2
- ASPM | c.4660C>G p.H1554D | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV54138914, COSV99659500; called by muse, mutect2, varscan2
- BCL11B | c.662A>G p.Y221C (on ENST00000357195 / NM_001282237.2; = p.Y150C on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100595131; called by muse, mutect2, varscan2
- BOC | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 12/103 reads (12%) | catalogued as rs1038611376, COSV99848041, COSV99848956; called by muse, mutect2, varscan2
- BPIFB6 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 143/612 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as COSV100848481; called by muse, mutect2, varscan2
- BRPF3 | c.1762G>T p.E588* | Nonsense Mutation (SNP) | VAF 21/117 reads (18%) | catalogued as COSV100325544; called by muse, mutect2, varscan2
- C6orf118 | c.29A>T p.Y10F | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.883); catalogued as COSV100024062; called by muse, mutect2, varscan2
- CACHD1 | c.1510G>T p.A504S | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.094); catalogued as COSV99261419; called by muse, mutect2, varscan2
- CASP8 | c.796G>A p.D266N (on ENST00000432109 / NM_033355.3; = p.D283N on NM_001228.4) | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51863244; called by muse, mutect2, varscan2
- CCDC59 | c.482A>T p.K161M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.2); catalogued as COSV99810504; called by muse, mutect2
- CCNB1 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.222); catalogued as rs1561313392, COSV99841199; called by muse, mutect2
- CDH11 | c.148C>A p.R50S | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51763225, COSV99217174; called by muse, mutect2, varscan2
- CDH9 | c.2054A>T p.D685V | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.367); catalogued as COSV99141576; called by muse, mutect2, varscan2
- CDH9 | c.2053G>T p.D685Y | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV50273979, COSV99157206; called by muse, mutect2, varscan2
- CDHR3 | c.1790C>A p.S597Y | Missense Mutation (SNP) | VAF 9/225 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100487963; called by muse, mutect2
- CFAP52 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100234775; called by muse, mutect2, varscan2
- CGN | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.521); catalogued as rs144180892, COSV99641873; called by muse, varscan2
- CKAP5 | c.3194C>G p.S1065C | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1223776872, COSV100370366; called by muse, mutect2, varscan2
- CLCN3 | c.347G>T p.W116L | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs1219530656, COSV100641575; called by muse, mutect2, varscan2
- CLDN19 | c.626A>T p.E209V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV56417872; called by muse, mutect2, varscan2
- CLEC14A | c.1327C>A p.L443M | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100643489; called by muse, mutect2, varscan2
- CLK1 | c.91A>G p.R31G | Missense Mutation (SNP) | VAF 116/338 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV100362125; called by muse, mutect2, varscan2
- CLYBL | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100184609; called by muse, mutect2, varscan2
- COL11A1 | c.463A>G p.R155G | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV100615073; called by muse, mutect2
- CREBBP | c.4395-2A>T p.X1465_splice | Splice Site (SNP) | VAF 34/127 reads (27%) | catalogued as COSV99268547; called by muse, mutect2, varscan2
- CSMD2 | c.6123C>A p.S2041R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as COSV99585951; called by muse, mutect2, varscan2
- CTNND2 | c.2333A>T p.E778V | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100471757; called by muse, varscan2
- CYBB | c.332A>T p.H111L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.528); catalogued as COSV101059679; called by muse, mutect2, varscan2
- CYGB | c.72G>C p.R24S | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as COSV99505945; called by muse, mutect2, varscan2
- DCBLD2 | c.2099C>A p.T700N | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as COSV54585903; called by muse, mutect2
- DEFA6 | c.218A>T p.H73L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as rs1354566851, COSV99857833; called by muse, varscan2
- DNAH10 | c.5539C>T p.R1847C (on ENST00000409039; = p.R1786C on NM_207437.3) | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs757448928, COSV68999645; called by muse, mutect2
- DNAH5 | c.9679A>G p.K3227E | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); catalogued as COSV99444916; called by muse, mutect2, varscan2
- DOCK5 | c.1013A>G p.D338G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99376007; called by muse, mutect2, varscan2
- DPP6 | c.1205C>G p.A402G (on ENST00000377770 / NM_001364500.2; = p.A340G on NM_001936.5) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV100123048, COSV59631831; called by muse, mutect2, varscan2
- DPRX | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100934045; called by muse, mutect2, varscan2
- DSEL | c.2090T>C p.I697T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV100025249; called by muse, mutect2, varscan2
- DYSF | c.2195C>G p.S732C | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as COSV50330247; called by muse, mutect2
- DZIP3 | c.1225C>G p.R409G | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as rs777080398, COSV100847620, COSV64312860; called by muse, mutect2, varscan2
- EHBP1 | c.3640C>G p.L1214V | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99860013; called by muse, mutect2
- EPHA5 | c.2955T>G p.I985M | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV99896121; called by muse, mutect2, varscan2
- EVI2B | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 110/475 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV100445374; called by muse, mutect2, varscan2
- EYA3 | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV100870206; called by muse, mutect2, varscan2
- FAM167B | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs747746477, COSV61107373; called by muse, mutect2, varscan2
- FMN2 | c.2927C>G p.P976R | Missense Mutation (SNP) | VAF 54/303 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.515); catalogued as COSV100142670; called by muse, varscan2
- FOLH1 | c.587G>T p.C196F | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as COSV99922677; called by muse, mutect2, varscan2
- FREM2 | c.1364G>T p.R455L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV99746764; called by muse, mutect2, varscan2
- FSCN3 | c.1111A>C p.I371L | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99756777; called by muse, mutect2
- FTO | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.953); catalogued as rs1358038241, COSV101149495; called by muse, mutect2
- GBP3 | c.647A>G p.N216S | Missense Mutation (SNP) | VAF 49/302 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99352344; called by muse, mutect2, varscan2
- GBX1 | c.416C>A p.P139Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV99880726; called by muse, mutect2, varscan2
- GOLGA3 | c.2099A>T p.Q700L | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV99202252; called by muse, mutect2
- GOLGB1 | c.1667A>G p.H556R | Missense Mutation (SNP) | VAF 48/229 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100510324; called by muse, mutect2, varscan2
- GPRC6A | c.1762A>T p.N588Y | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV100114008; called by muse, mutect2, varscan2
- GSK3B | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99954133; called by muse, mutect2, varscan2
- HCN4 | c.2665T>G p.S889A | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.122); catalogued as COSV99983268; called by muse, mutect2, varscan2
- HHIPL2 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 99/335 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as rs748201096, COSV100596583; called by muse, mutect2, varscan2
- HK2 | c.1612T>A p.F538I | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99308571; called by muse, mutect2
- HMCN1 | c.9742G>A p.A3248T | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.214); catalogued as COSV99624071; called by muse, mutect2, varscan2
- HMG20A | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV100287638, COSV60313254; called by muse, mutect2
- HSPA6 | c.968T>C p.L323P | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100553866; called by muse, mutect2, varscan2
- HTR1A | c.785A>G p.N262S | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs761353761, COSV100108905; called by muse, mutect2, varscan2
- IL4R | c.1580A>G p.E527G | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV99404684; called by muse, mutect2, varscan2
- INTS3 | c.2636G>A p.W879* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as COSV99669617, COSV99669686; called by muse, mutect2, varscan2
- IPO5 | c.1447G>T p.D483Y | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV99846972; called by muse, mutect2, varscan2
- IRF1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99810379; called by muse, mutect2, varscan2
- KCTD20 | c.424A>C p.M142L | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as COSV99535763; called by muse, mutect2, varscan2
- KDM6A | c.1009G>T p.A337S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100937898; called by muse, mutect2, varscan2
- KIF23 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99531835; called by muse, mutect2
- LAMC1 | c.542C>A p.S181Y | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99278953; called by muse, mutect2, varscan2
- LINGO3 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV68261173; called by muse, mutect2, varscan2
- LPCAT2 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100044425; called by muse, mutect2, varscan2
- LY75 | c.2145G>C p.L715F | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55105080, COSV99715947; called by muse, mutect2, varscan2
- MAGEC3 | c.1562A>T p.H521L | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100024828; called by muse, mutect2, varscan2
- MARCHF6 | c.2042G>C p.G681A | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99929338; called by muse, mutect2, varscan2
- MDN1 | c.11275G>C p.D3759H | Missense Mutation (SNP) | VAF 22/353 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); catalogued as COSV101020758; called by muse, mutect2
- MEIS1 | c.1010A>T p.Q337L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV99714450; called by muse, mutect2, varscan2
- MFAP3L | c.664G>C p.V222L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64372457; called by muse, mutect2, varscan2
- MITF | c.217A>T p.R73W | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100104845; called by muse, mutect2, varscan2
- MPP4 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as rs1249066146, COSV100206450; called by muse, mutect2, varscan2
- MUC16 | c.18049G>A p.G6017R | Missense Mutation (SNP) | VAF 43/315 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV101198084; called by muse, mutect2, varscan2
- MYO18B | c.6563G>C p.G2188A | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV100122580, COSV59140403; called by muse, mutect2, varscan2
- N4BP2 | c.2200C>G p.Q734E | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as COSV54704449, COSV99788189; called by muse, mutect2
- NAA25 | c.2663C>T p.T888I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV99927260; called by muse, mutect2, varscan2
- NAIP | c.417C>A p.D139E | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV99519140; called by muse, mutect2, varscan2
- NBEAL1 | c.6386G>C p.C2129S | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101355382; called by muse, mutect2
- NCBP2L | c.460T>C p.*154Qext*4 | Nonstop Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100966476; called by muse, mutect2, varscan2
- NDN | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100086214; called by muse, mutect2, varscan2
- NDUFA2 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV99346981; called by muse, mutect2, varscan2
- NEUROD4 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.045); catalogued as COSV54471803, COSV99669946; called by muse, mutect2, varscan2
- NF1 | c.3328T>G p.F1110V | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100646012; called by muse, mutect2, varscan2
- NFATC1 | c.2147G>T p.G716V | Missense Mutation (SNP) | VAF 95/390 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV99500551; called by muse, mutect2, varscan2
- NFE2L2 | c.320A>G p.H107R | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.063); catalogued as COSV101229302; called by muse, mutect2, varscan2
- NKX2-5 | c.280C>G p.P94A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV100234700; called by muse, mutect2
- NOD2 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs143782684; called by muse, mutect2, varscan2
- NPLOC4 | c.1373A>T p.K458M | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.238); catalogued as COSV100480604; called by muse, mutect2, varscan2
- NUP133 | c.1271C>G p.A424G | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.037); catalogued as COSV99772566; called by muse, mutect2
- OAZ2 | c.530T>C p.M177T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1365228878, COSV100386355; called by muse, mutect2, varscan2
- ODF2L | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 51/178 reads (29%) | catalogued as rs147978713, COSV99643807; called by muse, mutect2, varscan2
- OR11G2 | c.869A>T p.Y290F | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.434); catalogued as COSV100639907, COSV62132399; called by muse, mutect2
- OR11H12 | c.47A>C p.E16A | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV101612455; called by muse, mutect2, varscan2
- OR2L8 | c.175T>C p.Y59H | Missense Mutation (SNP) | VAF 237/789 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV100594025; called by muse, mutect2, varscan2
- OR2Z1 | c.604T>A p.S202T | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.326); catalogued as COSV100136325; called by muse, mutect2, varscan2
- OR4C3 | c.398T>C p.I133T | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs1286126144, COSV100167450; called by muse, mutect2, varscan2
- OR6M1 | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.284); catalogued as COSV100483997; called by muse, mutect2, varscan2
- OR8D1 | c.723C>A p.C241* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as COSV63443310; called by muse, mutect2, varscan2
- OR9G1 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs758510346, COSV100380228; called by muse, mutect2, varscan2
- OTOGL | c.6140G>C p.C2047S (on ENST00000547103; = p.C2038S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV100086681; called by muse, mutect2, varscan2
- PADI4 | c.1281G>T p.R427S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100966689; called by muse, mutect2, varscan2
- PCDHA5 | c.1930C>T p.H644Y | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV100972092; called by muse, mutect2, varscan2
- PCDHA5 | c.1931A>T p.H644L | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV100972093; called by muse, mutect2, varscan2
- PCDHAC1 | c.1421T>A p.L474Q | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.479); catalogued as COSV99165017; called by muse, mutect2, varscan2
- PCDHGA7 | c.2354G>T p.C785F | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV99530534; called by muse, mutect2, varscan2
- PCID2 | c.861-2A>T p.X287_splice | Splice Site (SNP) | VAF 9/55 reads (16%) | catalogued as COSV99872281; called by muse, mutect2, varscan2
- PDE3A | c.3425G>T p.*1142Lext*25 | Nonstop Mutation (SNP) | VAF 16/125 reads (13%) | catalogued as COSV100761648; called by muse, mutect2, varscan2
- PER1 | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100424241, COSV100424667; called by muse, mutect2, varscan2
- PER3 | c.3164C>T p.S1055F | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV100728205; called by muse, mutect2
- PFDN4 | c.196A>G p.M66V | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as rs569788589, COSV101004606; called by muse, mutect2, varscan2
- PKD1L1 | c.6595A>G p.R2199G | Missense Mutation (SNP) | VAF 118/422 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV99218392; called by muse, mutect2, varscan2
- PKHD1 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100580993; called by muse, mutect2, varscan2
- PKHD1L1 | c.4619A>T p.E1540V | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.218); catalogued as COSV101005351; called by muse, mutect2, varscan2
- PNPT1 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV99569578; called by muse, mutect2, varscan2
- POLH | c.1226C>A p.S409Y | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV64779851; called by muse, mutect2
- POLR3E | c.1945-1G>T p.X649_splice | Splice Site (SNP) | VAF 28/160 reads (18%) | catalogued as COSV100241902; called by muse, mutect2, varscan2
- PON1 | c.892A>T p.N298Y | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.144); catalogued as COSV55932100; called by muse, mutect2, varscan2
- PPIP5K2 | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100383425; called by muse, mutect2, varscan2
- PRPSAP1 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.098); catalogued as rs1305679852, COSV100221623; called by muse, mutect2, varscan2
- PTPN7 | c.745C>T p.H249Y (on ENST00000495688; = p.H288Y on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100459649; called by muse, mutect2, varscan2
- PTPRE | c.1236G>C p.Q412H | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99616871; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2284G>T p.A762S | Missense Mutation (SNP) | VAF 19/226 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.048); catalogued as COSV100741025; called by muse, mutect2
- RBM27 | c.1288A>G p.M430V | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.267); catalogued as rs1277842763, COSV99505661; called by muse, mutect2, varscan2
- RCVRN | c.41T>A p.L14Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99874069; called by muse, mutect2
- RFPL4B | c.668T>A p.V223D | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439631075, COSV101480653; called by muse, mutect2, varscan2
- RPL28 | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as rs750708696, COSV100689342; called by muse, mutect2, varscan2
- RYR1 | c.5123C>T p.A1708V | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV100614431; called by muse, mutect2
- SDR39U1 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs1566508533, COSV99249389; called by muse, mutect2, varscan2
- SEMA3E | c.606C>G p.I202M | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV100317270; called by muse, mutect2, varscan2
- SEMA5B | c.3323C>T p.P1108L | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.028); catalogued as COSV99530810; called by muse, mutect2, varscan2
- SH2B3 | c.1501C>T p.L501F | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as rs529644866, COSV100373997; called by muse, mutect2, varscan2
- SI | c.2255C>T p.T752I | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV100013940; called by muse, mutect2
- SI | c.1001T>C p.V334A | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1173323197, COSV52281551; called by muse, mutect2, varscan2
- SIX5 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99352732; called by muse, mutect2, varscan2
- SLC22A3 | c.1136T>G p.L379R | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV99278318; called by muse, mutect2, varscan2
- SLC22A8 | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100267698; called by muse, mutect2
- SLC5A10 | c.1028G>A p.G343E (on ENST00000395645 / NM_001042450.4; = p.G359E on NM_152351.5) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs773102593, COSV100524800; called by muse, mutect2, varscan2
- SLC8B1 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as COSV99176648; called by muse, mutect2, varscan2
- SLC9A2 | c.1529T>A p.V510E | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV99295835; called by muse, mutect2, varscan2
- SLCO1B3 | c.349T>C p.F117L | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV53935064, COSV99680771; called by muse, mutect2, varscan2
- SLIT2 | c.2012A>T p.Y671F | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV99880806; called by muse, mutect2, varscan2
- SLIT2 | c.3889C>T p.P1297S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV99880808; called by muse, mutect2, varscan2
- SMARCAL1 | c.2050A>G p.M684V | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as COSV100619745; called by muse, mutect2, varscan2
- SNCG | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100813793; called by muse, mutect2, varscan2
- SOAT1 | c.1553A>G p.Y518C | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100858878; called by muse, mutect2, varscan2
- SOBP | c.900G>C p.W300C | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100432772; called by muse, mutect2, varscan2
- SOS1 | c.3866G>T p.G1289V | Missense Mutation (SNP) | VAF 21/295 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.755); catalogued as COSV101216553; called by muse, mutect2
- SPANXN2 | c.134A>G p.K45R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.87); catalogued as COSV100979776, COSV65128974; called by muse, mutect2, varscan2
- SPOCD1 | c.3081C>A p.S1027R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV99929419; called by muse, mutect2, varscan2
- SPOPL | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99699312; called by muse, mutect2, varscan2
- SVIP | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100829761; called by muse, mutect2, varscan2
- TAF4B | c.1700T>A p.I567K | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV99299637; called by muse, mutect2
- TAS2R10 | c.809C>A p.P270H | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53701749, COSV99555417; called by muse, mutect2, varscan2
- TBC1D14 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as COSV101298746; called by muse, mutect2, varscan2
- TDP2 | c.563G>T p.R188I | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV100593548; called by muse, mutect2, varscan2
- TENT4A | c.2187G>T p.Q729H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.056); catalogued as COSV100048604, COSV50095465; called by muse, varscan2
- TEX2 | c.3296A>G p.Y1099C (on ENST00000583097 / NM_001288733.2; = p.Y1106C on NM_018469.5) | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as rs150394111, COSV51977361, COSV51984910; called by muse, mutect2, varscan2
- TGM5 | c.2143T>A p.Y715N (on ENST00000220420 / NM_201631.4; = p.Y633N on NM_004245.4) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV55011733; called by muse, mutect2, varscan2
- THBS2 | c.1236C>A p.S412R | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV64682534; called by muse, mutect2, varscan2
- TKTL2 | c.595G>T p.G199C | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99761091; called by muse, mutect2, varscan2
- TLN1 | c.5704C>T p.P1902S | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.02); catalogued as rs770507067, COSV100147282; called by muse, mutect2, varscan2
- TLR4 | c.2047C>A p.Q683K (on ENST00000355622 / NM_138554.5; = p.Q643K on NM_003266.4) | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0.041); catalogued as COSV100842651; called by muse, mutect2, varscan2
- TMCO3 | c.1982G>T p.R661I | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100952270, COSV64807981; called by muse, mutect2, varscan2
- TMEFF2 | c.185G>C p.R62T | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV99770993; called by muse, mutect2
- TMEM199 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as COSV50228404, COSV99134676; called by muse, mutect2, varscan2
- TMEM199 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.09); catalogued as COSV99134677; called by muse, mutect2, varscan2
- TMEM266 | c.1061C>A p.T354K | Missense Mutation (SNP) | VAF 104/288 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as COSV101189561; called by muse, mutect2, varscan2
- TNRC6B | c.4139T>A p.M1380K (on ENST00000454349 / NM_001162501.2; = p.M1270K on NM_015088.3) | Missense Mutation (SNP) | VAF 48/287 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100109016; called by muse, mutect2, varscan2
- TTN | c.5774T>G p.V1925G (on ENST00000591111; = p.V1879G on NM_003319.4) | Missense Mutation (SNP) | VAF 66/352 reads (19%) | PolyPhen probably damaging (0.998); catalogued as COSV100593866; called by muse, mutect2, varscan2
- TUBB4A | c.1086G>C p.K362N | Missense Mutation (SNP) | VAF 33/338 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.467); catalogued as COSV51152318, COSV99899851; called by muse, mutect2
- USP7 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100783973; called by muse, mutect2, varscan2
- VCAN | c.5014G>C p.D1672H | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV99424624; called by muse, mutect2, varscan2
- WDPCP | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs1284717514, COSV99703958; called by muse, mutect2, varscan2
- WDR31 | c.137A>T p.E46V (on ENST00000374193 / NM_001006615.3; = p.E45V on NM_145241.5) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV100516598; called by muse, mutect2, varscan2
- WDR31 | c.136G>T p.E46* (on ENST00000374193 / NM_001006615.3; = p.E45* on NM_145241.5) | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as COSV100516600, COSV100516785; called by muse, mutect2, varscan2
- ZEB1 | c.950C>A p.S317* | Nonsense Mutation (SNP) | VAF 14/79 reads (18%) | catalogued as COSV100313623; called by muse, mutect2, varscan2
- ZFP36L1 | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1174415515, COSV100322430; called by muse, mutect2, varscan2
- ZMIZ1 | c.3037G>A p.A1013T | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.08); catalogued as rs1470915263, COSV100565881; called by muse, mutect2, varscan2
- ZNF141 | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99549387; called by muse, mutect2, varscan2
- ZNF208 | c.267G>T p.Q89H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV101236808; called by muse, mutect2
- ZNF214 | c.1792C>A p.H598N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV99547148; called by muse, mutect2, varscan2
- ZNF34 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs563826645, COSV100603230; called by muse, mutect2
- ZNF518A | c.3416C>T p.T1139I | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.307); catalogued as rs1168396491, COSV100283329; called by muse, mutect2, varscan2
- ZNF549 | c.1787A>C p.Y596S (on ENST00000376233 / NM_001199295.2; = p.Y583S on NM_153263.2) | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.053); catalogued as COSV99558364; called by muse, mutect2, varscan2
- ZNF677 | c.38T>G p.V13G | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100447776; called by muse, mutect2
- ZNF701 | c.202G>T p.A68S (on ENST00000301093; = p.A2S on NM_018260.3) | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV99990630, COSV99990769; called by muse, mutect2
- ZNF804A | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as COSV100166392, COSV100167335; called by muse, mutect2, varscan2
- ZNF804B | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV100301737; called by muse, mutect2, varscan2
- ANK1 | c.2416_2417del p.F806Pfs*2 | Frame Shift Del (DEL) | VAF 12/100 reads (12%) | called by mutect2, pindel, varscan2
- CYB5B | c.191_192dup p.V65Rfs*9 | Frame Shift Ins (INS) | VAF 18/91 reads (20%) | called by mutect2, pindel, varscan2
- GPATCH8 | c.1123dup p.S375Ffs*18 | Frame Shift Ins (INS) | VAF 17/135 reads (13%) | called by mutect2, pindel, varscan2
- MUC16 | c.28107dup p.K9370Qfs*48 | Frame Shift Ins (INS) | VAF 46/195 reads (24%) | called by mutect2, pindel, varscan2
- PCDHB11 | c.1433_1436del p.R478Tfs*63 | Frame Shift Del (DEL) | VAF 32/338 reads (9%) | called by mutect2, pindel
- ZNF622 | c.886+2del p.X296_splice | Splice Site (DEL) | VAF 35/139 reads (25%) | called by mutect2, pindel, varscan2
- ADAM12 | c.39C>A p.A13= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100899992; called by muse, mutect2, varscan2
- ADAMTS18 | c.2679C>T p.Y893= | Silent (SNP) | VAF 47/185 reads (25%) | catalogued as COSV51419709, COSV99271123; called by muse, mutect2, varscan2
- ADGRF5 | c.3084A>C p.A1028= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV99344889; called by muse, mutect2, varscan2
- ADGRL2 | c.2490C>T p.L830= (on ENST00000370717 / NM_001366005.1; = p.L817= on NM_012302.4) | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as COSV99587033; called by muse, mutect2, varscan2
- ANAPC4 | c.1872A>G p.T624= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs202208886, COSV59547187; called by muse, mutect2, varscan2
- ANK2 | c.1701G>T p.L567= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV99999667; called by muse, mutect2, varscan2
- ARHGAP31 | c.2235G>T p.L745= | Silent (SNP) | VAF 18/165 reads (11%) | catalogued as COSV99956574; called by muse, mutect2
- ARNT2 | c.585G>C p.L195= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as rs1334913981, COSV100308505, COSV57585458; called by muse, mutect2, varscan2
- BTBD1 | c.1252C>T p.L418= | Silent (SNP) | VAF 9/124 reads (7%) | catalogued as COSV99915203; called by muse, mutect2
- CD163 | c.1461T>C p.C487= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100775642; called by muse, mutect2, varscan2
- CDAN1 | c.2862G>C p.P954= | Silent (SNP) | VAF 79/213 reads (37%) | catalogued as rs747935657, COSV100661146, COSV62330780; called by muse, mutect2, varscan2
- CENPE | c.2256A>G p.L752= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV99476970; called by muse, mutect2, varscan2
- CES5A | c.1074C>T p.I358= | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as COSV99307084; called by muse, mutect2
- CPAMD8 | c.1443G>A p.G481= (on ENST00000651564; = p.G434= on NM_015692.5) | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV52237468, COSV99358951; called by muse, mutect2, varscan2
- DIP2C | c.4665C>T p.N1555= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs750576476, COSV99789968; called by muse, mutect2, varscan2
- DMXL2 | c.3522A>G p.V1174= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs1291961046, COSV99195959; called by muse, mutect2, varscan2
- DNAJB14 | c.138A>G p.L46= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as rs779203083, COSV100508241; called by muse, mutect2, varscan2
- EIF4A1 | c.228C>T p.A76= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as COSV51512583; called by muse, mutect2, varscan2
- ERBB3 | c.2157C>T p.V719= | Silent (SNP) | VAF 31/444 reads (7%) | catalogued as COSV57258770, COSV99915743; called by muse, mutect2
- F9 | c.111C>A p.A37= | Silent (SNP) | VAF 43/133 reads (32%) | catalogued as COSV99496316; called by muse, mutect2, varscan2
- FAF1 | c.1170C>T p.F390= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as COSV100875255; called by muse, mutect2, varscan2
- FAHD1 | c.666A>T p.P222= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as COSV101232481; called by muse, mutect2, varscan2
- FAR2 | c.312T>C p.C104= | Silent (SNP) | VAF 51/173 reads (29%) | catalogued as COSV99478727; called by muse, mutect2, varscan2
- FAT4 | c.11031A>T p.T3677= | Silent (SNP) | VAF 17/134 reads (13%) | catalogued as COSV100627212; called by muse, mutect2, varscan2
- FGF21 | c.549C>A p.P183= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99711365; called by muse, mutect2, varscan2
- GFPT1 | c.1905G>T p.V635= (on ENST00000357308 / NM_001244710.2; = p.V617= on NM_002056.4) | Silent (SNP) | VAF 4/94 reads (4%) | catalogued as rs1558725033, COSV100622663; called by muse, mutect2
- HOXC11 | c.210C>G p.V70= | Silent (SNP) | VAF 51/241 reads (21%) | catalogued as COSV99678316; called by muse, mutect2, varscan2
- IFIT1B | c.99T>A p.P33= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as COSV100879040; called by muse, mutect2
- IGHG1 | c.171A>G p.L57= | Silent (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- IL36RN | c.150G>A p.L50= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs370859782; called by muse, mutect2, varscan2
- IMPDH1 | c.1092C>T p.G364= (on ENST00000470772 / NM_001142573.2; = p.G450= on NM_000883.4) | Silent (SNP) | VAF 27/133 reads (20%) | catalogued as rs780213373, COSV58315559; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCTD10 | c.933C>T p.L311= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV99949034; called by muse, mutect2, varscan2
- KHDRBS2 | c.231G>T p.V77= | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as rs767164811, COSV99830945; called by muse, mutect2, varscan2
- KIDINS220 | c.2307G>A p.L769= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV99874912; called by muse, mutect2
- KIR3DL1 | c.1251G>A p.R417= | Silent (SNP) | VAF 120/291 reads (41%) | catalogued as COSV100372825; called by muse, mutect2, varscan2
- LETM1 | c.354G>T p.S118= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs759752511, COSV100245202, COSV57101371; called by muse, mutect2, varscan2
- LILRA2 | c.255A>G p.P85= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV99252729; called by muse, mutect2
- MCOLN1 | c.1431C>T p.F477= | Silent (SNP) | VAF 35/289 reads (12%) | catalogued as rs745766983, COSV51174150; called by muse, mutect2, varscan2
- MRPS18A | c.342G>A p.K114= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV100928671; called by muse, mutect2, varscan2
- MUC16 | c.35379T>A p.P11793= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV101198082; called by muse, mutect2
- NCSTN | c.1119A>G p.S373= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs201642962, COSV99666742; called by muse, mutect2, varscan2
- NEDD1 | c.693C>T p.I231= | Silent (SNP) | VAF 41/151 reads (27%) | catalogued as rs746410089, COSV99900738; called by muse, mutect2, varscan2
- NOD2 | c.372C>T p.D124= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as rs753579507, COSV100318212; called by muse, mutect2, varscan2
- OR51B5 | c.723C>A p.S241= | Silent (SNP) | VAF 31/135 reads (23%) | catalogued as COSV56175319, COSV56176165; called by muse, mutect2, varscan2
- OR8B12 | c.696C>T p.G232= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100172634, COSV100172807; called by muse, mutect2, varscan2
- OR9A2 | c.675G>C p.P225= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as COSV100628162, COSV100628289; called by muse, mutect2, varscan2
- PAPPA2 | c.3474C>T p.C1158= | Silent (SNP) | VAF 11/144 reads (8%) | catalogued as rs1339464047, COSV100867558; called by muse, mutect2
- PCSK1 | c.624C>T p.H208= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as rs111380006, COSV100226799; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLOD2 | c.1917A>T p.A639= | Silent (SNP) | VAF 21/170 reads (12%) | catalogued as COSV99282344; called by muse, mutect2, varscan2
- POM121L12 | c.810G>A p.A270= | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as rs1217595031, COSV68692325; called by muse, mutect2, varscan2
- PPP6R1 | c.675G>A p.Q225= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as COSV101336941; called by muse, mutect2, varscan2
- RAB30 | c.513C>T p.I171= | Silent (SNP) | VAF 12/208 reads (6%) | catalogued as COSV99475534; called by muse, mutect2
- RELCH | c.2316A>G p.K772= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV99901411; called by muse, mutect2, varscan2
- RIMS1 | c.984A>G p.P328= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1042839595, COSV99324039; called by muse, mutect2, varscan2
- ROCK1 | c.4050T>C p.S1350= | Silent (SNP) | VAF 38/238 reads (16%) | catalogued as COSV101296232; called by muse, mutect2, varscan2
- SGCB | c.507G>A p.Q169= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV101197611; called by muse, mutect2, varscan2
- STX2 | c.543A>T p.I181= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV55432282, COSV99892370; called by muse, mutect2, varscan2
- SYCP1 | c.2787A>G p.P929= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs1200741790, COSV101050748; called by muse, mutect2
- TBC1D14 | c.669T>C p.A223= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV101298745; called by muse, mutect2, varscan2
- TIMM23 | c.579A>G p.L193= | Silent (SNP) | VAF 13/124 reads (10%) | catalogued as rs1554918142; called by muse, mutect2, varscan2
- TRAPPC10 | c.3090A>G p.G1030= | Silent (SNP) | VAF 51/165 reads (31%) | catalogued as COSV99378164; called by muse, mutect2, varscan2
- TRERF1 | c.2115G>T p.L705= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1219314353, COSV100549959; called by muse, mutect2, varscan2
- TRGV5 | c.213C>G p.S71= | Silent (SNP) | VAF 64/196 reads (33%) | called by muse, mutect2, varscan2
- TSACC | c.276A>G p.A92= | Silent (SNP) | VAF 73/209 reads (35%) | catalogued as rs749549434, COSV100966182; called by muse, mutect2, varscan2
- TTN | c.23967A>G p.S7989= (on ENST00000591111; = p.S7062= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/123 reads (7%) | catalogued as COSV100593865; called by muse, mutect2
- USH2A | c.5817A>G p.S1939= | Silent (SNP) | VAF 27/237 reads (11%) | catalogued as rs779180333, COSV100228891; called by muse, mutect2, varscan2
- VAV2 | c.2379C>G p.L793= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100895540; called by muse, mutect2, varscan2
- VRK3 | c.1068C>T p.F356= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs780493925, COSV100371278; called by muse, mutect2, varscan2
- WDR72 | c.2784T>A p.S928= | Silent (SNP) | VAF 15/124 reads (12%) | catalogued as COSV100854193; called by muse, mutect2, varscan2
- ZNF493 | c.402G>A p.Q134= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as COSV62750792; called by muse, mutect2
- ZNF610 | c.573A>G p.Q191= | Silent (SNP) | VAF 40/147 reads (27%) | catalogued as COSV100016701; called by muse, mutect2
- ZNF670 | c.36C>A p.A12= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV100829174; called by muse, mutect2, varscan2
- ZZEF1 | c.906C>A p.S302= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV101067472; called by muse, mutect2, varscan2
- ASCC3 | c.241+4881G>T | Intron (SNP) | VAF 16/161 reads (10%) | catalogued as COSV100225189; called by muse, mutect2, varscan2
- MIR129-1 | n.31del | RNA (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- OR2AK2 | c.-45A>G | 5'UTR (SNP) | VAF 12/48 reads (25%) | catalogued as rs750582807, COSV100823112; called by muse, mutect2
- SEC14L1 | c.*2531G>T | 3'UTR (SNP) | VAF 73/366 reads (20%) | catalogued as COSV66721091, COSV66724443; called by muse, mutect2, varscan2
- SEC14L1 | c.*2532A>G | 3'UTR (SNP) | VAF 72/365 reads (20%) | catalogued as COSV101170864; called by muse, mutect2, varscan2
- SSPOP | n.5844C>T | RNA (SNP) | VAF 24/103 reads (23%) | catalogued as COSV100022136; called by muse, mutect2, varscan2
